Somatic mutation profile of tumor specimen TCGA-BR-A4J8-01A (aliquot TCGA-BR-A4J8-01A-11D-A25D-08) from TCGA case TCGA-BR-A4J8, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 71.3 years (26,048 days).
Specimen TCGA-BR-A4J8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4eccd77f-f8a8-4bf2-b484-8080b861c666.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-A4J8-10A (Blood Derived Normal), aliquot TCGA-BR-A4J8-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ccb21ab6-5196-40d4-8342-3cb6db14aefa

The open-access MAF lists 93 somatic variants for this specimen: 61 protein-altering or splice-affecting, 31 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 31, Nonsense Mutation 4, Frame Shift Ins 2, Splice Region 2, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS15 | c.1047G>T p.E349D | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100143766; called by muse, mutect2, varscan2
- ANKRD12 | c.5263A>G p.T1755A | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV50853694; called by muse, mutect2
- APBB3 | c.1405G>A p.V469I (on ENST00000357560 / NM_133173.2; = p.V476I on NM_006051.3) | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs370414260; called by muse, mutect2, varscan2
- CCND2 | c.524C>T p.S175F | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs143681287, COSV54224084; called by mutect2, varscan2
- CDH20 | c.491A>C p.K164T | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.881); catalogued as COSV53019087; called by muse, mutect2, varscan2
- CIITA | c.2378T>A p.L793Q | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60862698; called by muse, mutect2, varscan2
- CLCN6 | c.1033G>A p.G345S | Missense Mutation (SNP) | VAF 12/419 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56741551; called by muse, mutect2
- DDO | c.263G>C p.G88A | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.697); catalogued as COSV64470725; called by muse, mutect2
- DDX39A | c.407C>T p.S136F | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV54393585; called by muse, mutect2, varscan2
- DNAAF4 | c.755G>A p.R252H | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs889125391, COSV100336966, COSV58251964; called by muse, mutect2, varscan2
- DOK2 | c.827A>T p.D276V | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV52390355; called by muse, mutect2, varscan2
- DST | c.16823C>T p.A5608V (on ENST00000361203 / NM_001374722.1; = p.A3305V on NM_015548.5) | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.766); catalogued as rs764588106, COSV54999109; called by muse, mutect2, varscan2
- EIF2B4 | c.1496T>C p.L499P (on ENST00000347454 / NM_001034116.2; = p.L498P on NM_015636.3) | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as COSV61458237; called by muse, mutect2, varscan2
- ELMO1 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.182); catalogued as COSV60294929; called by muse, mutect2
- ERBB4 | c.1074C>A p.N358K | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.486); catalogued as COSV53594061; called by muse, mutect2, varscan2
- EXO1 | c.589C>T p.Q197* | Nonsense Mutation (SNP) | VAF 19/201 reads (9%) | catalogued as COSV62220221; called by muse, mutect2
- FAM20B | c.727C>T p.R243* | Nonsense Mutation (SNP) | VAF 43/108 reads (40%) | catalogued as rs757361941, COSV55382918; called by muse, mutect2, varscan2
- FSIP2 | c.19522T>G p.L6508V | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.073); catalogued as COSV100556403; called by muse, mutect2, varscan2
- GABRQ | c.946C>T p.R316W | Missense Mutation (SNP) | VAF 58/124 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs376489228, COSV64780814; called by muse, mutect2, varscan2
- GPT2 | c.1479C>T p.F493= | Splice Region (SNP) | VAF 16/85 reads (19%) | catalogued as COSV60840463; called by muse, mutect2, varscan2
- GRIA4 | c.1678G>A p.V560M | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.832); catalogued as rs778053723, COSV56922206; called by muse, mutect2, varscan2
- IRS1 | c.395G>A p.G132D | Missense Mutation (SNP) | VAF 73/103 reads (71%) | SIFT tolerated (0.45); PolyPhen benign (0.093); catalogued as COSV59340758; called by muse, mutect2, varscan2
- KLHL14 | c.89A>T p.Q30L | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.932); catalogued as COSV63835836; called by muse, mutect2, varscan2
- LEPR | c.2696T>C p.F899S | Missense Mutation (SNP) | VAF 17/244 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62752566; called by muse, mutect2
- LPXN | c.376G>T p.A126S | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as COSV67718332; called by muse, mutect2, varscan2
- MAGEA10 | c.1018A>T p.R340* | Nonsense Mutation (SNP) | VAF 52/181 reads (29%) | catalogued as COSV54886250; called by muse, mutect2, varscan2
- MARCHF10 | c.1231C>A p.Q411K | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.93); PolyPhen benign (0.071); catalogued as COSV60890786; called by muse, mutect2, varscan2
- MEIOC | c.1573T>G p.L525V | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.038); catalogued as COSV63441661; called by muse, mutect2, varscan2
- MRGPRX2 | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.67); catalogued as rs1166014845, COSV61674413; called by muse, mutect2, varscan2
- MUC5B | c.13135A>C p.T4379P | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.363); catalogued as COSV71596067; called by muse, mutect2, varscan2
- MYO15A | c.922G>A p.G308S | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.03); catalogued as rs1326631616, COSV52767456; called by muse, mutect2, varscan2
- NCOA3 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV59074031; called by muse, mutect2
- NPPB | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.86); PolyPhen benign (0.107); catalogued as rs756326340, COSV100916074, COSV64687934; called by muse, mutect2, varscan2
- NPR3 | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775585104, COSV54093751; called by muse, mutect2, varscan2
- OR52K1 | c.892A>T p.T298S | Missense Mutation (SNP) | VAF 30/178 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV56904939; called by muse, mutect2, varscan2
- OR56B1 | c.744C>A p.S248R | Missense Mutation (SNP) | VAF 21/182 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.182); catalogued as COSV57724061; called by muse, mutect2, varscan2
- OR6C2 | c.404A>G p.N135S | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.01); catalogued as COSV59517127; called by muse, mutect2
- PDZRN3 | c.2830C>T p.R944W | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs750997558, COSV55205737; called by muse, mutect2, varscan2
- PEAK1 | c.1843A>G p.T615A | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs536431798, COSV56944325; called by muse, mutect2, varscan2
- PLBD2 | c.985A>T p.K329* | Nonsense Mutation (SNP) | VAF 10/45 reads (22%) | catalogued as COSV55109224; called by muse, mutect2, varscan2
- POGLUT1 | c.820G>A p.V274I | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.788); catalogued as rs776985194, COSV55158794; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTGFR | c.79C>T p.R27W | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.296); catalogued as rs749469257, COSV66116927; called by muse, mutect2
- RAG1 | c.2952C>G p.C984W | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.219); catalogued as COSV55028820; called by muse, mutect2
- RPS6KA6 | c.1127C>T p.P376L | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as COSV53127607, COSV99425461; called by muse, mutect2, varscan2
- S100A9 | c.259A>C p.T87P | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.825); catalogued as COSV64199908; called by muse, mutect2, varscan2
- SHOX | c.546C>T p.G182= | Splice Region (SNP) | VAF 9/44 reads (20%) | catalogued as rs138998412, COSV61862495; called by muse, mutect2, varscan2
- SLC44A4 | c.660G>T p.K220N | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.415); catalogued as COSV57669368; called by muse, mutect2, varscan2
- SLITRK6 | c.2345T>C p.L782P | Missense Mutation (SNP) | VAF 10/169 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); catalogued as COSV68391913; called by muse, mutect2
- SNRNP40 | c.355A>G p.T119A | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as COSV55279890; called by muse, mutect2
- SRPRA | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 8/123 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.196); catalogued as COSV55009268; called by muse, mutect2
- STX18 | c.7G>A p.V3M | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.081); catalogued as COSV60376372; called by muse, mutect2
- SULF1 | c.1168G>T p.D390Y | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV52694661, COSV99484127; called by muse, mutect2
- TOM1L2 | c.478T>G p.S160A (on ENST00000379504 / NM_001350333.2; = p.S110A on NM_001033551.3) | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as COSV58889296; called by muse, mutect2
- TOX | c.593G>T p.S198I | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.103); catalogued as COSV63851192; called by muse, mutect2, varscan2
- TP53 | c.582dup p.I195Yfs*14 | Frame Shift Ins (INS) | VAF 24/57 reads (42%) | catalogued as COSV53719420; called by mutect2, pindel, varscan2
- TTLL5 | c.367C>G p.P123A | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54045245; called by muse, mutect2, varscan2
- URB2 | c.803C>T p.T268M | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs114879838, COSV51057232; called by muse, mutect2, varscan2
- XK | c.563A>G p.N188S | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.779); catalogued as COSV66120267, COSV66120981; called by muse, mutect2
- ZNFX1 | c.2035C>T p.R679W | Missense Mutation (SNP) | VAF 32/215 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65575243; called by muse, mutect2, varscan2
- ARID1A | c.2175_2193del p.P726Sfs*10 | Frame Shift Del (DEL) | VAF 20/70 reads (29%) | called by mutect2, pindel, varscan2
- CD248 | c.878_884dup p.H295Qfs*14 | Frame Shift Ins (INS) | VAF 6/31 reads (19%) | called by mutect2, varscan2
- ADAMTS2 | c.3156G>A p.S1052= | Silent (SNP) | VAF 78/386 reads (20%) | catalogued as rs763966576, COSV52371388; called by muse, mutect2, varscan2
- ADGRG4 | c.1113T>C p.S371= | Silent (SNP) | VAF 28/64 reads (44%) | catalogued as COSV54968561; called by muse, mutect2, varscan2
- AFM | c.1665G>A p.V555= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as COSV56922536; called by muse, mutect2
- BMP3 | c.597T>A p.S199= | Silent (SNP) | VAF 12/140 reads (9%) | catalogued as COSV51096467; called by muse, mutect2
- CARD11 | c.1056G>A p.S352= | Silent (SNP) | VAF 33/202 reads (16%) | catalogued as rs145169161; called by muse, mutect2, varscan2
- CENPF | c.5721C>T p.I1907= | Silent (SNP) | VAF 7/139 reads (5%) | catalogued as COSV100871771, COSV65279633; called by muse, mutect2
- CTNNA3 | c.960G>A p.T320= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as COSV65609538; called by muse, mutect2, varscan2
- DCAF12L2 | c.600C>T p.V200= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as rs771849328, COSV63584441; called by muse, mutect2, varscan2
- DECR1 | c.900C>T p.D300= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as rs766014372, COSV55168271; called by muse, mutect2, varscan2
- DSP | c.8505C>G p.S2835= | Silent (SNP) | VAF 23/78 reads (29%) | catalogued as rs1381413030, COSV60940364, COSV60940949; called by muse, mutect2, varscan2
- E2F7 | c.150A>G p.E50= | Silent (SNP) | VAF 18/81 reads (22%) | catalogued as COSV59741356; called by muse, mutect2, varscan2
- EEF1A2 | c.447C>T p.I149= | Silent (SNP) | VAF 15/200 reads (8%) | catalogued as rs772964838, COSV53208572; ClinVar: likely benign; called by muse, mutect2
- EPB41L3 | c.2490G>A p.T830= | Silent (SNP) | VAF 18/123 reads (15%) | catalogued as rs747043897, COSV59469707; called by muse, mutect2, varscan2
- ERBIN | c.2499T>C p.P833= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV52328115; called by muse, mutect2, varscan2
- FZD2 | c.1398C>T p.S466= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as rs772686055, COSV59530438; called by muse, mutect2, varscan2
- IGKC | c.219G>A p.T73= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as rs537902669; called by muse, mutect2, varscan2
- KCNJ2 | c.882C>T p.I294= | Silent (SNP) | VAF 14/83 reads (17%) | catalogued as rs751279819, COSV54664076, COSV99696545; called by muse, mutect2, varscan2
- LEP | c.333G>T p.L111= | Silent (SNP) | VAF 14/105 reads (13%) | catalogued as COSV58241610; called by muse, mutect2, varscan2
- NAXE | c.610C>T p.L204= | Silent (SNP) | VAF 16/101 reads (16%) | catalogued as COSV58041717; called by muse, mutect2, varscan2
- NSMF | c.1515G>A p.T505= (on ENST00000371475 / NM_001130969.3; = p.T503= on NM_015537.4) | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as rs778638506, COSV55811675; called by muse, mutect2, varscan2
- OR1M1 | c.388T>C p.L130= | Silent (SNP) | VAF 22/120 reads (18%) | catalogued as COSV70037585; called by muse, mutect2, varscan2
- PDLIM4 | c.930G>A p.V310= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV53805580; called by muse, mutect2, varscan2
- PJVK | c.1002G>A p.K334= | Silent (SNP) | VAF 63/206 reads (31%) | catalogued as COSV51847800; called by muse, mutect2, varscan2
- PLCG2 | c.1854C>T p.R618= | Silent (SNP) | VAF 26/345 reads (8%) | catalogued as rs566722658, COSV63872921; called by muse, mutect2
- PRPF4 | c.237C>T p.S79= (on ENST00000374198 / NM_001322267.2; = p.S80= on NM_004697.5) | Silent (SNP) | VAF 15/89 reads (17%) | catalogued as rs745966548, COSV65253521; called by muse, mutect2, varscan2
- PRUNE2 | c.624C>T p.I208= | Silent (SNP) | VAF 28/127 reads (22%) | catalogued as COSV65029863; called by muse, mutect2, varscan2
- RBP3 | c.2625C>T p.G875= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as rs142862418; called by muse, mutect2, varscan2
- SH3TC1 | c.1605C>T p.D535= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs750026686, COSV55290551; called by mutect2, varscan2
- SNRNP200 | c.523C>T p.L175= | Silent (SNP) | VAF 177/297 reads (60%) | catalogued as rs750891688, COSV60495058; called by muse, mutect2, varscan2
- TCN2 | c.1264C>T p.L422= | Silent (SNP) | VAF 8/90 reads (9%) | catalogued as COSV53193291; called by muse, mutect2
- TELO2 | c.1713A>T p.G571= | Silent (SNP) | VAF 40/228 reads (18%) | catalogued as COSV51981671; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65502280 T>A | 5'Flank (SNP) | VAF 3/19 reads (16%) | called by muse, mutect2
